Surgical pathology report (de-identified scan), TCGA case TCGA-06-0185, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-0185-01A (Primary Tumor).

[page 1 of 2]
TCGA-06-0185

Surgical Pathology Report

CLINICAL HISTORY

[REDACTED] with heterogeneously enhancing right temporal lobe tumor.

OPERATIVE DIAGNOSES
Not Given

Operation/Specimen: Temporal right Brain, biopsy

PATHOLOGICAL DIAGNOSIS:
Brain, right temporal, excision: Glioblastoma.
See comment.

COMMENT

The specimen is portions of cerebrum diffusely infiltrated and extensively effaced by a glial neoplastic proliferation. The neoplastic cells have an astrocyte phenotype, nuclear atypia, mitotic activity, microvascular cellular proliferation, and extensive zones of necrosis, i.e., a glioblastoma.

PROCEDURES/ADDENDA

Immunohistology

Date Ordered: [REDACTED] Date Reported: [REDACTED]

Interpretation
MIB1 PROLIFERATION INDEX: 12%.

Results-Comments

IMMUNOHISTOCHEMISTRY: The GFAP demonstrates sparse gliofibrillogenesis by the neoplastic cells. Only about 2% of neoplastic cells over express the p53 protein. The NFP is non reactive. There is a MIB1 proliferation index of about 12% in the more active areas.

[page 2 of 2]
Interpretation

The immuno findings described below support the glioblastoma diagnosis. TCGA-06-0180

Results-Comments

IMMUNOHISTOCHEMISTRY: The neuronal markers (chromogranin and synaptophysin) demonstrate a neuropil background focally at the infiltrative edge of the tumor, and some entrapped neurons within the neoplasm. These neurons are interpreted as non-neoplastic. The CD34 depicts a rich capillary-type vascular network throughout the tumor, with focal microvascular proliferation.

GROSS DESCRIPTION

SPECIMEN: Right temporal tumor.

FIXATIVE: Formalin.

GENERAL: A 7.0 x 5.0 x 2.0 cm., 19.56 gm. aggregate of a few fragments of red to gray-tan brain tissue. The fragments are sectioned and along edges are scattered petechiae and tan-yellow discoloration.

SECTIONS: A1-A5 - representative.

ICD-9(s):

191.2 191.2

Histo Data

Part A: Temporal right Brain, biopsy

Taken:	Received:	Block	Ordered	Comment
Stain/cnt		1		
H/E x 1		2		
H/E x 1		3		
H/E x 1		4		
CD34-DA x 1		4		
ChromA-DA x 1		4		
mGFAP-DA x 1		4		
H/E x 1		4		
MIB1-DA x 1		4		
NF2F11 x 1		4		
P53DO7 x 1		4		
Synap-DA x 1		4		
H/E x 1		5		

*** End of Report ***

Source: NCI Genomic Data Commons file c9b79c2b-273f-4886-8a69-32291e5c237e (TCGA-06-0185.4DD513D8-FF26-465B-B99D-6BF738BF7911.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).